Somatic mutation profile of tumor specimen TCGA-CV-5442-01A (aliquot TCGA-CV-5442-01A-01D-1512-08) from TCGA case TCGA-CV-5442, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hard palate; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 76.8 years (28,040 days).
Specimen TCGA-CV-5442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bf344ed-a498-4a0a-83d7-4421cacf0611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5442-11A (Solid Tissue Normal), aliquot TCGA-CV-5442-11A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f1d1d37-e23a-4f13-bf79-4959fc58d9fe

The open-access MAF lists 253 somatic variants for this specimen: 200 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 49, Nonsense Mutation 17, Frame Shift Ins 4, Splice Region 2, Intron 1, 3'UTR 1, Frame Shift Del 1, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACP5 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV99520348; called by muse, mutect2, varscan2
- ADGRV1 | c.6340G>A p.D2114N | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101316052; called by muse, mutect2, varscan2
- ADNP | c.3173C>G p.S1058C | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV100823756, COSV62425337; called by muse, mutect2, varscan2
- AL136295.1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 184/497 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV99937790, COSV99938063; called by muse, mutect2, varscan2
- AP1G1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs1428976744, COSV55494305; called by muse, mutect2, varscan2
- APBA1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1564062638, COSV55228003; called by muse, mutect2, varscan2
- ARHGAP21 | c.2636C>G p.S879* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as COSV100256256; called by muse, mutect2, varscan2
- ARID1B | c.5464G>A p.E1822K | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51657278, COSV99269647; called by muse, mutect2, varscan2
- ARSB | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs368295181; called by muse, mutect2, varscan2
- ARSF | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.24); catalogued as rs761840114, COSV100839519; called by muse, mutect2, varscan2
- ASB6 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52964296; called by muse, mutect2, varscan2
- ATP11C | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100558024; called by muse, mutect2, varscan2
- BMX | c.1229G>T p.W410L | Missense Mutation (SNP) | VAF 97/409 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100564477; called by muse, mutect2, varscan2
- BNC2 | c.1889A>T p.K630M | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101033396; called by muse, mutect2, varscan2
- C6 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs780174708, COSV99667163; called by muse, mutect2, varscan2
- CADM2 | c.461C>A p.A154E (on ENST00000407528 / NM_001167674.2; = p.A156E on NM_153184.4) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101056217; called by muse, mutect2, varscan2
- CAPN12 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as COSV100185298; called by muse, varscan2
- CC2D1A | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1202650332, COSV54308298; called by muse, mutect2, varscan2
- CDH20 | c.2052G>C p.W684C | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV99404759, COSV99405536; called by muse, mutect2, varscan2
- CEP57L1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1211429581, COSV61245465; called by muse, mutect2, varscan2
- CEP89 | c.2249G>A p.R750K | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV99993520; called by muse, varscan2
- CFHR4 | c.140C>A p.A47E (on ENST00000367416 / NM_001201551.2; = p.A48E on NM_006684.5) | Missense Mutation (SNP) | VAF 160/260 reads (62%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); catalogued as COSV99260573; called by muse, mutect2, varscan2
- CHD6 | c.4068G>A p.T1356= | Splice Region (SNP) | VAF 30/160 reads (19%) | catalogued as rs764835276, COSV100498327; called by muse, mutect2, varscan2
- CLEC6A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV101165657; called by muse, mutect2, varscan2
- CLIP4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs764347800, COSV60747867; called by muse, mutect2, varscan2
- CNTN1 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.058); catalogued as COSV100751479; called by muse, mutect2, varscan2
- CNTN3 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 130/487 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV55165846, COSV99724634; called by muse, mutect2, varscan2
- COG4 | c.975C>A p.F325L | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV100091829; called by muse, mutect2, varscan2
- COL19A1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs187031631, COSV100505808, COSV59589366, COSV59590663; called by muse, mutect2
- COL4A1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV101011204; called by muse, mutect2, varscan2
- CP | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT tolerated (0.55); PolyPhen benign (0.133); catalogued as rs767188986, COSV99224147; called by muse, varscan2
- CSMD3 | c.4798C>T p.L1600F (on ENST00000297405 / NM_001363185.1; = p.L1496F on NM_052900.3) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV52158139, COSV99835789; called by muse, mutect2, varscan2
- DBH | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1452172409, COSV67548797; called by muse, mutect2, varscan2
- DCTN4 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.71); catalogued as COSV101437559; called by muse, mutect2, varscan2
- DDX50 | c.2209G>C p.D737H | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV101007253; called by muse, mutect2, varscan2
- DDX59 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as COSV100494564; called by muse, mutect2, varscan2
- DHX29 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99287325; called by muse, mutect2, varscan2
- DKK1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1419285519, COSV100906543, COSV64760484; called by muse, mutect2, varscan2
- DLEC1 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100342496, COSV57299544; called by muse, mutect2, varscan2
- DNAH1 | c.9840G>C p.E3280D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750353986, COSV101325948; called by muse, varscan2
- DNAJC8 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV99746310; called by muse, mutect2, varscan2
- DOCK8 | c.2962G>C p.E988Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.181); catalogued as rs540409876, COSV101209940; called by muse, mutect2, varscan2
- EFTUD2 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV101274542; called by muse, mutect2, varscan2
- EIF4G1 | c.2860C>T p.R954* (on ENST00000346169 / NM_198241.3; = p.R759* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 32/153 reads (21%) | catalogued as COSV100071849; called by muse, mutect2, varscan2
- ESPL1 | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 66/176 reads (38%) | catalogued as COSV99229381; called by muse, mutect2, varscan2
- FAM117A | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.568); catalogued as rs368403545; called by muse, mutect2, varscan2
- FAM184A | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV100137857, COSV58855486; called by muse, mutect2, varscan2
- FARS2 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as rs1187765069, COSV51170370, COSV99213029; called by muse, mutect2, varscan2
- FGG | c.512T>A p.I171N | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271896; called by muse, mutect2, varscan2
- FLT1 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99160381; called by muse, mutect2, varscan2
- FRMD7 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs868852708, COSV100049044; called by muse, mutect2, varscan2
- GALNT2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV100795780; called by muse, mutect2, varscan2
- GATAD2B | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100897881; called by muse, mutect2, varscan2
- GBP5 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100600084; called by muse, mutect2, varscan2
- GFM2 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764685887, COSV99714405; called by muse, mutect2, varscan2
- GGA2 | c.1008C>G p.V336= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as COSV59168272; called by muse, mutect2, varscan2
- GIGYF2 | c.2887G>C p.E963Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65251621; called by muse, mutect2
- GLIS3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs376905545; called by muse, mutect2, varscan2
- GNL1 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100925426; called by muse, mutect2, varscan2
- GPAM | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100788237; called by muse, mutect2, varscan2
- GPR107 | c.1649C>T p.S550L (on ENST00000372406 / NM_001136557.2; = p.S502L on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347097040, COSV100714672; called by muse, mutect2, varscan2
- GRIK5 | c.2027C>A p.T676N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99490633; called by muse, mutect2, varscan2
- GRK3 | c.886T>A p.F296I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100151602; called by muse, mutect2, varscan2
- GRM7 | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV100736791; called by muse, mutect2, varscan2
- GYG2 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772512411, COSV100089016; called by muse, mutect2, varscan2
- HCCS | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.27); catalogued as rs144634482, COSV100335691; called by muse, mutect2, varscan2
- HDAC9 | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101286787; called by muse, mutect2, varscan2
- HECTD1 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1326871119, COSV101125705; called by muse, mutect2, varscan2
- HENMT1 | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100898665, COSV64230358; called by muse, mutect2, varscan2
- HNF4G | c.353C>T p.S118L (on ENST00000354370 / NM_001330561.2; = p.S165L on NM_004133.5) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs756032593, COSV100584554, COSV62967299; called by muse, mutect2, varscan2
- HNF4G | c.786G>A p.M262I (on ENST00000354370 / NM_001330561.2; = p.M309I on NM_004133.5) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs1472701590, COSV62971368; called by muse, mutect2, varscan2
- HS2ST1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs762375562, COSV100777758, COSV100777789; called by muse, mutect2, varscan2
- HUWE1 | c.10759-2A>T p.X3587_splice | Splice Site (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99472577; called by muse, mutect2, varscan2
- IBTK | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); catalogued as COSV100090831; called by muse, mutect2, varscan2
- IGBP1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV60556742; called by muse, mutect2, varscan2
- INTS1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV101247951, COSV67176609; called by muse, mutect2, varscan2
- INTS7 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100877503; called by muse, mutect2, varscan2
- IRS2 | c.339C>G p.I113M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101019129; called by muse, mutect2, varscan2
- ITIH1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs763101480, COSV99835290; called by muse, mutect2, varscan2
- JAG2 | c.3092G>A p.S1031N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as COSV100078459; called by muse, mutect2, varscan2
- KDF1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57670792; called by muse, mutect2, varscan2
- KDM2B | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as rs1216237512, COSV100997428; called by muse, mutect2, varscan2
- KDM5C | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100949224; called by muse, mutect2, varscan2
- KIF18A | c.2378A>G p.N793S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99588745; called by muse, mutect2, varscan2
- KIF4A | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.749); catalogued as COSV100979538; called by muse, mutect2, varscan2
- KMT2C | c.4252C>G p.P1418A | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs375541673, COSV100072415; called by muse, mutect2, varscan2
- KRT19 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99563075; called by muse, mutect2, varscan2
- KRT38 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV55845561; called by muse, mutect2, varscan2
- LAMA3 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs545342009, COSV58082310, COSV58084586; called by muse, mutect2, varscan2
- LARP1B | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99218318; called by muse, mutect2, varscan2
- LMTK2 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 240/423 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV99806951; called by muse, mutect2, varscan2
- LSAMP | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61312683; called by muse, mutect2, varscan2
- LURAP1L | c.595T>G p.L199V | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100070746; called by muse, mutect2, varscan2
- MAGI2 | c.2509A>C p.T837P | Missense Mutation (SNP) | VAF 195/283 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100834715; called by muse, mutect2, varscan2
- MAGI3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100289278; called by muse, mutect2, varscan2
- MAGI3 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773507498, COSV100287849, COSV56841973; called by muse, mutect2, varscan2
- MEIS1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.573); catalogued as COSV55488234, COSV99715283; called by muse, mutect2
- MYH10 | c.3047C>A p.A1016D | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV99345333; called by muse, mutect2, varscan2
- MYNN | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.932); catalogued as COSV100582063; called by muse, mutect2, varscan2
- MYOM2 | c.2881G>T p.V961L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs140995511; called by muse, mutect2, varscan2
- MYT1L | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 86/222 reads (39%) | catalogued as COSV67734103; called by muse, varscan2
- NBAS | c.5263G>C p.D1755H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99870008, COSV99870112; called by muse, mutect2, varscan2
- NCOA3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.615); catalogued as COSV100507625; called by muse, mutect2, varscan2
- NCOR2 | c.810C>G p.I270M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100657380; called by muse, mutect2, varscan2
- NCSTN | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs867404939, COSV99667189; called by muse, mutect2, varscan2
- NEUROD4 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54473558, COSV99669935; called by muse, mutect2, varscan2
- NFASC | c.2422G>A p.G808R (on ENST00000339876 / NM_001378329.1; = p.G804R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58358822; called by muse, mutect2, varscan2
- NID1 | c.2134G>C p.D712H | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99937579; called by muse, mutect2, varscan2
- NLGN2 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs754926986, COSV100081035; called by muse, mutect2, varscan2
- NPPA | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100411960; called by muse, mutect2, varscan2
- NXPE4 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100970455; called by muse, mutect2, varscan2
- OR1M1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 35/264 reads (13%) | catalogued as COSV101447562; called by muse, mutect2, varscan2
- OR52I1 | c.34A>T p.T12S | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100331725; called by muse, mutect2
- PAX5 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 150/493 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1313118042, COSV63905600; called by muse, mutect2, varscan2
- PCBP2 | c.524dup p.K176Efs*46 | Frame Shift Ins (INS) | VAF 35/76 reads (46%) | catalogued as rs776329515; called by mutect2, varscan2
- PCDHA11 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1187011496, COSV56481398; called by muse, mutect2, varscan2
- PCNT | c.6877G>A p.E2293K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs753722099, COSV64030512; called by muse, mutect2, varscan2
- PDK4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV99138837; called by muse, mutect2, varscan2
- PDZD2 | c.8375G>A p.G2792E | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225178; called by muse, mutect2, varscan2
- PGC | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100757007; called by muse, mutect2, varscan2
- PLA2G4E | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762214857, COSV101268582; called by muse, mutect2, varscan2
- PLA2G7 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99221406; called by muse, mutect2, varscan2
- PLCB4 | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937563733, COSV99595600; called by muse, mutect2, varscan2
- POU2F2 | c.893G>A p.R298H (on ENST00000526816 / NM_001207025.3; = p.R282H on NM_002698.5) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100657369; called by muse, mutect2, varscan2
- PPP1R3F | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs968825820, COSV99278774; called by muse, mutect2, varscan2
- PRDM14 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99400217; called by muse, mutect2, varscan2
- PRKD1 | c.1680C>G p.I560M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV100120466; called by muse, mutect2, varscan2
- PRMT8 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99713428; called by muse, mutect2, varscan2
- PSMD2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs753938322, COSV59530262; called by muse, mutect2, varscan2
- RAPGEF3 | c.1703A>C p.D568A (on ENST00000389212; = p.D526A on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99406399; called by muse, mutect2, varscan2
- RASEF | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as rs748960349, COSV64589300; called by muse, mutect2, varscan2
- RBMXL2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.301); catalogued as rs1373039155, COSV100182271, COSV100182323; called by muse, mutect2, varscan2
- RELN | c.9751G>A p.E3251K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as rs376520049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 120/205 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs752821338, COSV100633889, COSV59039167; called by muse, mutect2, varscan2
- RFPL3 | c.424G>A p.D142N (on ENST00000249007 / NM_001098535.1; = p.D113N on NM_006604.2) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV99967105; called by muse, mutect2, varscan2
- RHOXF1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as rs1556000394, COSV54295436; called by muse, varscan2
- RIMS2 | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1468519050, COSV51693360; called by muse, mutect2, varscan2
- RNF13 | c.1042G>C p.D348H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV99526048; called by muse, mutect2, varscan2
- RNF213 | c.8834G>A p.R2945H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs76918558, COSV60389944; called by muse, mutect2, varscan2
- RPS6KA6 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV53116827, COSV53121021; called by muse, mutect2, varscan2
- RYR1 | c.4963C>T p.R1655C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs371777056; called by muse, varscan2
- SCN10A | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV101479348, COSV101479410; called by muse, mutect2, varscan2
- SCN7A | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101313246; called by muse, mutect2, varscan2
- SF3A2 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.725); catalogued as rs755308302, COSV99677863; called by muse, mutect2, varscan2
- SFRP4 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.559); catalogued as rs1562852039, COSV52257882; called by muse, mutect2, varscan2
- SHOC1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV100597666; called by muse, mutect2, varscan2
- SKP2 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 88/465 reads (19%) | catalogued as COSV99948116; called by muse, mutect2, varscan2
- SLC5A8 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73310519; called by muse, mutect2, varscan2
- SLC9A3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1229485554, COSV99376198; called by muse, mutect2, varscan2
- SLITRK2 | c.181dup p.Q61Pfs*35 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs781792891; called by mutect2, varscan2
- SMC3 | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100699929; called by muse, mutect2, varscan2
- SNAPC4 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100047283; called by muse, mutect2, varscan2
- SNX18 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100410459; called by muse, mutect2, varscan2
- SORCS1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99547019; called by muse, varscan2
- SPAG11B | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as rs774762278; called by mutect2, varscan2
- SPATA19 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100141111, COSV54485196; called by muse, mutect2, varscan2
- SREK1IP1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV101536178; called by muse, mutect2, varscan2
- STAT1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 27/32 reads (84%) | catalogued as COSV100738666; called by muse, mutect2, varscan2
- STIM2 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52836374; called by muse, mutect2, varscan2
- STRAP | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374693662, COSV99214806; called by muse, mutect2, varscan2
- SUPT16H | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99359905; called by muse, mutect2, varscan2
- SYMPK | c.3349G>C p.E1117Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.177); catalogued as COSV99679814; called by muse, mutect2
- SYNE1 | c.25765C>T p.Q8589* (on ENST00000367255 / NM_182961.4; = p.Q8541* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | catalogued as COSV99566192; called by muse, mutect2, varscan2
- SYNM | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100152768; called by muse, mutect2, varscan2
- TBC1D1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765507688, COSV99791366; called by muse, mutect2, varscan2
- TCERG1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.355); catalogued as COSV99694949; called by muse, mutect2, varscan2
- TEP1 | c.2660C>A p.P887H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV52988827, COSV99402499; called by muse, mutect2, varscan2
- TEX264 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV100392636; called by muse, mutect2, varscan2
- TIMM44 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 150/567 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV99564091; called by muse, mutect2, varscan2
- TINF2 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 117/258 reads (45%) | catalogued as COSV99945544; called by muse, mutect2, varscan2
- TLN2 | c.7027G>C p.E2343Q | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100169125; called by muse, mutect2, varscan2
- TLR9 | c.1890G>C p.L630F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100645663; called by muse, mutect2, varscan2
- TLR9 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs202131815, COSV62346098; called by muse, mutect2, varscan2
- TM2D2 | c.353C>T p.S118L (on ENST00000456397 / NM_078473.3; = p.S75L on NM_031940.4) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100205759; called by muse, mutect2, varscan2
- TM9SF2 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs1352576026, COSV100899717; called by muse, mutect2, varscan2
- TMF1 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 46/183 reads (25%) | catalogued as rs200769311, COSV101275436; called by muse, mutect2, varscan2
- TMIGD1 | c.779C>G p.T260R | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187250; called by muse, mutect2, varscan2
- TNKS | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs773491393, COSV100127104; called by muse, mutect2, varscan2
- TNRC6B | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.556); catalogued as rs372960539; called by muse, mutect2, varscan2
- TRIO | c.7705G>A p.E2569K | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100702595; called by muse, mutect2
- TRPC6 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60253771; called by muse, mutect2, varscan2
- TRPM6 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62503678, COSV62516773; called by muse, mutect2, varscan2
- TTC21B | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV99692387; called by muse, mutect2, varscan2
- UHRF2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV99436775; called by muse, mutect2, varscan2
- UHRF2 | c.2359C>G p.L787V | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99436778; called by muse, mutect2, varscan2
- VPS41 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100053930; called by muse, mutect2, varscan2
- ZBTB48 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV100887249; called by muse, mutect2, varscan2
- ZIC1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1335082823, COSV99291978; called by muse, mutect2, varscan2
- ZNF211 | c.1246C>T p.R416W (on ENST00000347302 / NM_198855.4; = p.R429W on NM_006385.5) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs373659490; called by muse, mutect2, varscan2
- ZNF354C | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.127); catalogued as COSV100203657; called by muse, mutect2, varscan2
- ZNF407 | c.3079C>G p.H1027D | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1418255817, COSV55259270, COSV99995826; called by muse, mutect2, varscan2
- ZNF549 | c.310C>T p.H104Y (on ENST00000376233 / NM_001199295.2; = p.H91Y on NM_153263.2) | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99558601; called by muse, mutect2, varscan2
- ZNF573 | c.790C>T p.H264Y (on ENST00000536220 / NM_001172692.1; = p.H206Y on NM_152360.3) | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265641; called by muse, varscan2
- ZSCAN4 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV99990018; called by muse, mutect2, varscan2
- C8orf33 | c.273dup p.E92Rfs*13 | Frame Shift Ins (INS) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- CXCR3 | c.449_452dup p.N152Pfs*209 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MICAL1 | c.1674del p.E559Sfs*15 | Frame Shift Del (DEL) | VAF 75/271 reads (28%) | called by mutect2, pindel, varscan2
- CFAP52 | c.1110C>T p.I370= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100235260; called by muse, mutect2
- CPVL | c.529C>A p.R177= | Silent (SNP) | VAF 75/91 reads (82%) | catalogued as COSV55304803, COSV99605080, COSV99605884; called by muse, mutect2, varscan2
- CRB1 | c.3468C>T p.D1156= | Silent (SNP) | VAF 71/132 reads (54%) | catalogued as rs771091006, COSV100957902; called by muse, mutect2, varscan2
- CTCFL | c.1905C>T p.V635= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as rs141206026, COSV99712791; called by muse, mutect2, varscan2
- CXXC1 | c.330G>A p.K110= | Silent (SNP) | VAF 62/157 reads (39%) | catalogued as rs201658397, COSV99496423; called by muse, mutect2, varscan2
- DAP3 | c.135G>A p.P45= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as rs768657534, COSV58021415; called by muse, mutect2, varscan2
- DNAH8 | c.10278G>A p.L3426= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV100545626; called by muse, mutect2, varscan2
- EIF4E1B | c.537C>G p.V179= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100024721; called by muse, varscan2
- GARS1 | c.328C>T p.L110= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as COSV101220122; called by muse, mutect2, varscan2
- GBP2 | c.636G>A p.K212= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100975397; called by muse, mutect2, varscan2
- GMIP | c.2817G>A p.E939= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99179307; called by muse, mutect2, varscan2
- GOLT1A | c.147C>T p.I49= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV100383481; called by muse, mutect2, varscan2
- GRAMD4 | c.1521G>A p.R507= | Silent (SNP) | VAF 84/202 reads (42%) | catalogued as rs896517159, COSV100730499; called by muse, mutect2, varscan2
- HNF4A | c.39C>T p.A13= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as rs373591956, COSV100291159; called by muse, mutect2, varscan2
- IGFN1 | c.3003C>T p.L1001= (on ENST00000295591 / NM_001367841.1; = p.L3458= on NM_001164586.2) | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99812514; called by muse, mutect2, varscan2
- IL19 | c.75C>T p.L25= | Silent (SNP) | VAF 46/284 reads (16%) | catalogued as COSV99536339; called by muse, mutect2, varscan2
- KIF2C | c.486G>A p.L162= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as rs1400570109, COSV100945728, COSV64764438; called by muse, mutect2, varscan2
- MAGI2 | c.798G>A p.E266= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV100834718, COSV62675407; called by muse, mutect2, varscan2
- MAST3 | c.2238G>A p.L746= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53219793; called by muse, mutect2
- MFSD5 | c.1201C>A p.R401= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs767465967, COSV100289055, COSV61565493; called by muse, mutect2, varscan2
- MRO | c.273C>G p.L91= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV56496083, COSV99839291; called by muse, mutect2, varscan2
- MYO1F | c.1593G>C p.L531= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV100596733; called by muse, mutect2, varscan2
- NAGA | c.738G>A p.G246= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1351913352, COSV101124152; called by muse, mutect2, varscan2
- NOC4L | c.1170C>T p.F390= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100400117; called by muse, mutect2, varscan2
- NPY5R | c.81C>T p.F27= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV58452473; called by muse, mutect2, varscan2
- NRXN3 | c.2373C>T p.T791= (on ENST00000335750 / NM_001330195.2; = p.T418= on NM_004796.6) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs767156426, COSV100204361; called by muse, mutect2, varscan2
- NTF3 | c.318G>A p.L106= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1347287032, COSV100451107; called by muse, mutect2, varscan2
- NUTM2F | c.993C>T p.P331= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99480157; called by muse, mutect2, varscan2
- OR2T2 | c.354C>T p.L118= | Silent (SNP) | VAF 26/351 reads (7%) | catalogued as rs1438304620, COSV100737676; called by muse, mutect2
- OR2T2 | c.867C>A p.L289= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV100737677; called by muse, mutect2, varscan2
- OR4C3 | c.585G>T p.L195= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV100167881; called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PCDHB15 | c.1326G>A p.S442= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as rs1187877073, COSV99178954; called by muse, mutect2, varscan2
- PEA15 | c.384G>A p.K128= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100470494; called by muse, mutect2, varscan2
- PLOD3 | c.612G>C p.L204= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV56181439, COSV56182750, COSV99778051; called by muse, mutect2
- PPP1R21 | c.244C>T p.L82= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV54287864, COSV99682122; called by muse, mutect2, varscan2
- PSMC2 | c.261C>G p.L87= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV99485314; called by muse, mutect2, varscan2
- SEMA3C | c.57G>A p.V19= | Silent (SNP) | VAF 47/200 reads (24%) | catalogued as COSV99543091; called by muse, mutect2, varscan2
- SH3KBP1 | c.591C>T p.N197= | Silent (SNP) | VAF 70/256 reads (27%) | catalogued as rs773098443, COSV101114807; called by muse, varscan2
- SLC24A4 | c.1377C>T p.T459= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs764395598, COSV100105278; called by muse, mutect2, varscan2
- SNRK | c.1131C>G p.L377= | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as COSV99939137; called by muse, mutect2, varscan2
- SON | c.6333G>A p.Q2111= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV51657391; called by muse, mutect2, varscan2
- SSTR1 | c.321C>T p.L107= | Silent (SNP) | VAF 94/266 reads (35%) | catalogued as COSV57455764, COSV57457049; called by muse, mutect2, varscan2
- STRBP | c.777C>T p.G259= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs751593665, COSV62121021; called by muse, mutect2, varscan2
- TBC1D10A | c.459G>A p.V153= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99304681; called by muse, mutect2, varscan2
- TGM4 | c.1590G>A p.S530= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs528006561, COSV99942370; called by muse, mutect2, varscan2
- VAV1 | c.1119C>G p.V373= | Silent (SNP) | VAF 40/392 reads (10%) | catalogued as COSV100409099; called by muse, varscan2
- VIT | c.90G>A p.T30= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs147850488; called by muse, mutect2, varscan2
- ZNF106 | c.3630G>A p.E1210= | Silent (SNP) | VAF 88/220 reads (40%) | catalogued as COSV99782665; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827655 A>G | 3'Flank (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1412G>A | 3'UTR (SNP) | VAF 11/19 reads (58%) | catalogued as rs548817695, COSV53407950; called by muse, varscan2
- RUSC1 | c.-86-281C>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as COSV52740082, COSV99429874, COSV99430304; called by muse, mutect2, varscan2
- SNORD115-30 | n.39G>A | RNA (SNP) | VAF 76/223 reads (34%) | called by muse, mutect2, varscan2
